Gene-level copy-number profile of tumor specimen HCM-BROD-0100-C15-01A from HCMI case HCM-BROD-0100-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 64.4 years (23,514 days).
Specimen HCM-BROD-0100-C15-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 016dab6a-a33d-49b5-bef8-62add92ec383.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0100-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,739 have no estimate.
https://portal.gdc.cancer.gov/files/bf2ec751-0a3a-479e-943e-8ba83bb6e88a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 32; copy number 1: 2,946; copy number 2: 31,757; copy number 3: 15,222; copy number 4: 5,291; copy number 5: 2,902; copy number 6: 294; copy number 7: 37; copy number 8: 178; copy number 9: 38; copy number 10: 15; copy number 12: 75; copy number 14: 14; copy number 15: 12; copy number 16: 4; copy number 20: 26; copy number 22: 9; copy number 24: 2; copy number 30: 30.

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,690,225–60,690,719, 1 gene (within-gene range 0–1): PPIAP70.
- chr9:9,442,060–10,532,411, 3 genes (within-gene range 0–2): RN7SL5P, AL513422.1, AL135790.2.
- chr11:80,321,620–81,556,425, 7 genes: AP006295.1, RNU6-544P, ARL6IP1P3, LINC02720, AP003398.1, MTND4LP18, MTND6P25.
- chr16:78,825,281–79,110,882, 10 genes (within-gene range 0–2): RPS3P7, AC136603.1, AC027279.4, AC027279.1, AC027279.3, AC027279.2, AC009145.4, AC009145.3, AC009145.1, AC009145.2.
- chr17:18,426,861–18,442,895, 2 genes: KRT17P2, KRT16P1.
- chr17:18,452,955–18,506,313, 5 genes (within-gene range 0–2): AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2.
- chr17:57,448,218–57,532,355, 3 genes (within-gene range 0–2): AC015883.1, AC007431.2, AC007431.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,619 genes in 40 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:82,476,825–82,538,711, 1 gene, copy number 6: AC010105.1.
- chr3:77,811,741–77,811,844, 1 gene, copy number 7: RNU6-217P.
- chr3:149,030,127–149,291,800, 7 genes, copy number 5 (within-gene range 4–5): HLTF, HLTF-AS1, Y_RNA, MED28P2, HPS3, CP, CPHL1P.
- chr5:94,111,720–95,961,851, 31 genes, copy number 5–7: AC117528.1, KIAA0825, MTND5P12, MTND6P3, MTCYBP35, AC093311.1, AC025766.1, SLF1, MCTP1, AC008534.1, RPL7P18, AC008534.2, MCTP1-AS1, FAM81B, RTRAFP2, TTC37, RNU6-308P, ARSK, GPR150, RFESD, SPATA9, AC008840.1, RHOBTB3, GLRX, HSPD1P11, GGCTP1, AC008592.3, LINC01554, AC008592.4, AC008592.1, ELL2.
- chr5:95,964,999–96,215,519, 6 genes, copy number 7 (within-gene range 2–7): AC008592.2, FABP5P5, MIR583HG, MIR583, RNU6-524P, AC099509.1.
- chr6:41,683,978–44,089,696, 95 genes, copy number 6–24 (broad region; genes not listed).
- chr6:44,387,706–45,664,349, 14 genes, copy number 5–8: CDC5L, MIR4642, AL136140.1, AL136140.2, AL133334.1, SUPT3H, NUDT19P4, AL138880.2, RBM22P4, AL138880.1, MIR586, RUNX2, AL096865.1, RUNX2-AS1.
- chr6:170,615,515–170,738,536, 1 gene, copy number 6 (within-gene range 3–6): AL672310.1.
- chr6:170,736,173–170,737,777, 1 gene, copy number 6: AL731684.1.
- chr7:37,032–27,269,678, 464 genes, copy number 5 (broad region; genes not listed).
- chr7:42,661,716–51,389,114, 159 genes, copy number 5 (broad region; genes not listed).
- chr7:54,933,699–56,176,412, 44 genes, copy number 5: AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2, AC092647.5, ZNF713, NIPSNAP2, MRPS17, PSPH, CCT6A, SNORA22B, SNORA15, SUMF2, PHKG1, CHCHD2, NUPR2, IFITM3P4, AC006970.1.
- chr8:42,128,774–42,271,266, 6 genes, copy number 5: AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1.
- chr8:46,028,804–89,243,793, 622 genes, copy number 5 (broad region; genes not listed).
- chr8:89,585,872–100,131,268, 185 genes, copy number 5 (broad region; genes not listed).
- chr8:100,257,060–122,127,184, 252 genes, copy number 5 (broad region; genes not listed).
- chr9:32,293,558–34,628,086, 97 genes, copy number 5 (broad region; genes not listed).
- chr9:35,490,111–35,561,898, 2 genes, copy number 6 (within-gene range 4–6): RUSC2, AL133476.1.
- chr9:35,561,831–36,830,456, 54 genes, copy number 6: FAM166B, RPS29P17, TESK1, MIR4667, CD72, AL357874.2, AL357874.1, SIT1, RMRP, RMRP, CCDC107, ARHGEF39, RN7SL22P, CA9, TPM2, TLN1, MIR6852, CREB3, MIR6853, GBA2, RGP1, MSMP, AL133410.2, AL133410.1, NPR2, SPAG8, HINT2, AL133410.3, TMEM8B, FAM221B, OR13E1P, OR13J1, NDUFA5P4, HRCT1, SPAAR, PGAM1P2, OR2S2, OR2S1P, YBX1P10, OR13C6P, OR13C7, OR2AM1P, RECK, AL138834.1, GLIPR2, CCIN, CLTA, GNE, RNU4-53P, HMGB3P24, RNF38, MELK, AL450267.2, MIR4475.
- chr9:64,878,790–64,889,063, 2 genes, copy number 12: AC125634.1, RNU6-1293P.
- chr15:84,884,654–89,398,487, 85 genes, copy number 6–9 (broad region; genes not listed).
- chr15:95,990,582–96,842,384, 27 genes, copy number 5: AC012409.2, AC024337.1, AC024337.2, NR2F2-AS1, AC012409.5, AC012409.3, AC012409.1, AC012409.4, LINC02157, AC016251.1, NR2F2, MIR1469, AC103746.1, AC087477.2, TUBAP12, AC087477.5, AC087477.3, PGAM1P12, AC087477.1, AC087477.4, RN7SKP254, Metazoa_SRP, AC110588.1, FAM149B1P1, SPATA8-AS1, SPATA8, RN7SKP181.
- chr15:97,533,738–98,420,998, 17 genes, copy number 8: AC026523.2, AC026523.1, AC026523.3, AC026523.4, LINC00923, AC024651.2, ARRDC4, AC024651.1, LINC02251, AC022523.1, RNU6-1186P, LINC01582, AC022523.3, AC022523.2, AC015722.1, AC015722.2, LINC02351.
- chr16:9,541,970–32,824,645, 804 genes, copy number 5–6 (broad region; genes not listed).
- chr16:32,869,985–32,888,874, 3 genes, copy number 12: BCAP31P2, SLC6A10P, AC142086.1.
- chr17:29,560,547–29,707,090, 9 genes, copy number 15 (within-gene range 2–15): ABHD15, ABHD15-AS1, TP53I13, AC104564.3, GIT1, ANKRD13B, AC104564.4, CORO6, AC104564.2.
- chr17:29,639,627–29,645,847, 3 genes, copy number 15 (within-gene range 2–15): AC104564.1, RNU6-920P, AC104564.5.
- chr17:36,377,531–36,457,535, 4 genes, copy number 16 (within-gene range 3–16): TBC1D3H, RNU6-1192P, TBC1D3F, TBC1D3J.
- chr17:36,634,069–40,885,242, 172 genes, copy number 5–30 (broad region; genes not listed).
- chr17:49,788,648–51,171,744, 74 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr17:71,011,997–72,640,472, 14 genes, copy number 20 (within-gene range 1–20): AC005181.1, CASC17, RNU7-155P, AC118653.1, MYL6P5, ROCR, LINC01152, AC007461.1, SOX9-AS1, LINC02097, SOX9, LINC00511, LINC02003, AC007639.1.
- chr17:73,163,035–73,911,878, 19 genes, copy number 8–22: POLR3KP2, AC097641.1, SSTR2, COG1, AC097641.2, FAM104A, C17orf80, AC087301.1, CPSF4L, CDC42EP4, SDK2, AC124804.1, AC032019.1, AC032019.2, AC125421.1, LINC00469, LINC02092, AC125421.2, AC137735.1.
- chr17:75,165,586–75,289,510, 7 genes, copy number 6 (within-gene range 3–6): SUMO2, NUP85, GGA3, MRPS7, MIF4GD, AC022211.2, SLC25A19.
- chr17:75,874,164–76,005,999, 11 genes, copy number 5 (within-gene range 3–5): TRIM47, AC087289.5, TRIM65, AC087289.2, MRPL38, AC087289.3, FBF1, ACOX1, AC087289.4, TEN1-CDK3, TEN1.
- chr19:27,681,072–29,015,160, 32 genes, copy number 6–10: LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532.
- chr19:33,555,568–36,125,947, 144 genes, copy number 5–8 (broad region; genes not listed).
- chr19:36,150,922–36,246,257, 5 genes, copy number 5: COX7A1, AC002984.1, ZNF565, Y_RNA, ZNF146.
- chr20:61,252,261–61,940,617, 2 genes, copy number 5 (within-gene range 4–5): CDH4, AL365229.1.
- chr20:61,432,868–64,327,972, 139 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr22:18,615,581–18,653,617, 4 genes, copy number 6: Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2.

Autosomal genes at a single copy (total copy number 1): 654. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
